Gene-level copy-number profile of tumor specimen TCGA-DC-6154-01A from TCGA case TCGA-DC-6154, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Age at diagnosis: 57.7 years (21,093 days).
Specimen TCGA-DC-6154-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.422827b1-b4be-496a-a991-24e228e8a48b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DC-6154-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d8b8c638-bc0c-4211-90fc-29128e3b32b1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 1,676; copy number 2: 31,924; copy number 3: 19,898; copy number 4: 5,266; copy number 5: 117; copy number 6: 250; copy number 8: 595; copy number 13: 12; copy number 15: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DC-6154-01A-31D-1923-01): tumor purity 0.86, ploidy 2.47, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:5,381,641–8,974,580, 60 genes: AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P, L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1, AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2.
- chr20:14,884,250–14,935,363, 2 genes (within-gene range 0–1): MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 992 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:20,567,138–21,094,714, 18 genes, copy number 15 (within-gene range 3–15): IFT88, SLC35E1P1, RNU2-7P, AL161772.1, IL17D, AL512652.2, EEF1AKMT1, RANP8, AL512652.1, XPO4, CNOT4P1, HNRNPA1P30, PPIAP27, RPSAP54, LATS2, LATS2-AS1, RNU4-9P, RPS12P23.
- chr13:27,819,376–28,138,193, 12 genes, copy number 13: PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1.
- chr13:113,883,667–114,337,626, 16 genes, copy number 6: BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr20:25,407,673–64,313,132, 946 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,676. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
